Somatic mutation profile of tumor specimen TCGA-HU-8244-01A (aliquot TCGA-HU-8244-01A-11D-2340-08) from TCGA case TCGA-HU-8244, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 77.2 years (28,184 days).
Specimen TCGA-HU-8244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fced14ed-a6f4-4e7e-80a3-f5441845994c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8244-10A (Blood Derived Normal), aliquot TCGA-HU-8244-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57d30f74-fd72-4b18-8adc-d4031270c168

The open-access MAF lists 136 somatic variants for this specimen: 90 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 43, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.1225-1G>A p.X409_splice (on ENST00000382580 / NM_001005735.2; = p.X366_splice on NM_007194.4) | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as rs1060502716, COSV100101890, COSV60424264; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3994G>A p.G1332R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775914750, COSV101315511, COSV67983679; called by muse, mutect2, varscan2
- AL441992.2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs572629163, COSV56912492; called by muse, mutect2, varscan2
- AMY2A | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs549614263, COSV70214663; called by mutect2, varscan2
- AQP1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748039521, COSV61266109; called by muse, mutect2, varscan2
- C6orf118 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1257110834, COSV57817906; called by muse, mutect2, varscan2
- CAMK1G | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99151706; called by muse, mutect2, varscan2
- CCDC120 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1272845419, COSV64515264; called by muse, mutect2, varscan2
- CDH11 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99218745; called by muse, mutect2
- CDK8 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV67419693; called by muse, mutect2, varscan2
- CEP72 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53798067, COSV99374924; called by muse, mutect2, varscan2
- COL4A1 | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011258; called by muse, mutect2, varscan2
- COL6A3 | c.6343G>A p.D2115N | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1300930286, COSV99798987; called by muse, mutect2, varscan2
- CRAT | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100540015; called by muse, mutect2, varscan2
- CROCC | c.3290G>A p.R1097Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs6669627, COSV65013770; called by muse, varscan2
- CTNNA2 | c.1259T>G p.V420G | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100560060, COSV58135013, COSV58149761; called by muse, mutect2, varscan2
- DCAF12L1 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs776193696, COSV64421592; called by muse, mutect2, varscan2
- DKK1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100906547; called by muse, mutect2, varscan2
- DOP1B | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764951278, COSV67694499; called by muse, mutect2, varscan2
- EBF1 | c.1007A>G p.K336R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as rs1207301073, COSV100565937; called by muse, mutect2
- EBF1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1156409738, COSV58167858; called by muse, mutect2, varscan2
- FAM47A | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV60493807, COSV60494503; called by muse, varscan2
- FARS2 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV99213046; called by muse, mutect2, varscan2
- FAT3 | c.12005G>A p.R4002H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1227402217, COSV53129249; called by muse, mutect2, varscan2
- GATA3 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100651055; called by muse, mutect2, varscan2
- H2BW1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs782445882, COSV54220675; called by muse, mutect2, varscan2
- HECA | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100866226; called by muse, mutect2, varscan2
- HSD11B1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554862870, COSV54825694; called by muse, mutect2, varscan2
- HSPG2 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as rs1332584154, COSV65930008; called by muse, mutect2, varscan2
- HTR1A | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV60503838; called by muse, mutect2, varscan2
- IGF1R | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455239044, COSV104389926, COSV99151682; called by muse, mutect2, varscan2
- ITGA11 | c.2561C>T p.T854M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs774539684, COSV59877277; called by muse, mutect2, varscan2
- KCNB2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs370327292; called by muse, mutect2, varscan2
- KCNMA1 | c.3290G>A p.R1097H (on ENST00000286628 / NM_001161352.2; = p.R1039H on NM_002247.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54292640; called by muse, mutect2, varscan2
- KCNV2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs746359393, COSV101172609, COSV66057010; called by muse, mutect2, varscan2
- KIF21B | c.4306C>T p.R1436C (on ENST00000422435 / NM_001252100.2; = p.R1423C on NM_017596.4) | Missense Mutation (SNP) | VAF 90/129 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361814429, COSV100144656; called by muse, mutect2, varscan2
- KIF3C | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV53101905, COSV99267482; called by muse, mutect2, varscan2
- KNDC1 | c.4498G>A p.V1500I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs779018201, COSV58837176; called by muse, mutect2, varscan2
- LRFN1 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); catalogued as COSV50526636; called by muse, mutect2, varscan2
- LRP2 | c.4196C>G p.S1399C | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV99788920; called by muse, mutect2, varscan2
- LTA | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs368539892; called by muse, mutect2, varscan2
- LYSMD1 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54859509; called by muse, mutect2, varscan2
- MAP7D1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772737835, COSV100294568; called by muse, mutect2, varscan2
- MDN1 | c.6761G>A p.R2254H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021460; called by muse, mutect2, varscan2
- MS4A14 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100280507; called by muse, mutect2
- MUC5AC | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); catalogued as rs768950562, COSV62254118; called by muse, mutect2, varscan2
- MUC5AC | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); catalogued as rs554248382, COSV100650619; called by muse, mutect2, varscan2
- MYO5C | c.3755G>A p.R1252H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1211888232, COSV99954897; called by muse, mutect2, varscan2
- NEB | c.4909G>T p.A1637S | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99424239; called by muse, mutect2, varscan2
- NUTM2F | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767402497, COSV99480189; called by muse, mutect2, varscan2
- OAS2 | c.2136T>A p.N712K | Missense Mutation (SNP) | VAF 103/206 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as COSV100660193; called by muse, mutect2, varscan2
- OR4A16 | c.479T>C p.F160S | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.199); catalogued as COSV100125273; called by muse, mutect2, varscan2
- OR5H1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100641656, COSV63402017; called by muse, mutect2, varscan2
- OR7C1 | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV50183016; called by muse, mutect2, varscan2
- PAPOLG | c.1538A>G p.N513S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs138135157; called by muse, mutect2, varscan2
- PCDH17 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64975650; called by muse, mutect2, varscan2
- PCDHGA12 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV99340596; called by muse, mutect2, varscan2
- PKP1 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99825360; called by muse, mutect2, varscan2
- PTPRO | c.1717A>C p.M573L | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99840775; called by muse, mutect2, varscan2
- RIMS1 | c.3409T>C p.S1137P | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as COSV99327624; called by muse, mutect2, varscan2
- RPGRIP1L | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs777088047, COSV100046432; called by muse, mutect2, varscan2
- SAP30 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99633085; called by mutect2, varscan2
- SCAF11 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991973393, COSV101014316; called by muse, mutect2, varscan2
- SCAP | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs758490301, COSV99652880, COSV99653462; called by muse, mutect2, varscan2
- SETD5 | c.3437C>G p.S1146* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100200756; called by muse, mutect2
- SIL1 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99498191; called by muse, mutect2, varscan2
- SLC29A2 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1339086340, COSV100237128; called by muse, mutect2, varscan2
- SLC5A7 | c.1279G>T p.V427F | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1297408485, COSV99886811; called by muse, mutect2, varscan2
- SLITRK5 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs758176397, COSV100280873; called by muse, mutect2, varscan2
- SOCS7 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs145376452; called by muse, mutect2, varscan2
- SREBF1 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs776419406; called by muse, varscan2
- STXBP1 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV100964593; called by muse, mutect2, varscan2
- SYNE1 | c.2335C>G p.Q779E (on ENST00000367255 / NM_182961.4; = p.Q786E on NM_033071.3) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV99567670; called by muse, mutect2, varscan2
- SYNE2 | c.12478G>A p.G4160R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100647890, COSV59953666; called by muse, mutect2, varscan2
- SYNE3 | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs756639179, COSV62078342; called by muse, mutect2, varscan2
- SYTL2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV100314401; called by muse, mutect2, varscan2
- TEP1 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs779605418, COSV52987617; called by muse, mutect2, varscan2
- TP53BP1 | c.4630G>A p.V1544M | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780728; called by muse, mutect2, varscan2
- TRDN | c.134G>C p.S45T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100522290, COSV62121137; called by muse, mutect2, varscan2
- UBE3D | c.103A>T p.M35L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52752021; called by muse, mutect2, varscan2
- WDR89 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV99962461; called by muse, mutect2, varscan2
- XPO7 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs769149146, COSV99381463; called by muse, mutect2, varscan2
- ZBED1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100585641; called by muse, mutect2, varscan2
- ZBTB3 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101188976; called by muse, mutect2, varscan2
- ZC3H3 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs780265755, COSV99368021; called by muse, mutect2, varscan2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- HEATR4 | c.223_256del p.Q75Ffs*43 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by mutect2, pindel
- KIF21A | c.387dup p.H130Tfs*5 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- TGFBRAP1 | c.690dup p.M231Hfs*35 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel
- ABHD2 | c.606C>T p.V202= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs1279474200, COSV61774043; called by muse, mutect2, varscan2
- ACD | c.961C>T p.L321= (on ENST00000620338; = p.L232= on NM_022914.3) | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as rs1483246179, COSV99537765; called by muse, mutect2, varscan2
- APOB | c.13671A>G p.G4557= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as COSV99266087; called by muse, mutect2, varscan2
- AQP7 | c.639C>T p.I213= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs187791092, COSV99952988; called by muse, mutect2, varscan2
- ATG2A | c.5178C>T p.G1726= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV101034504, COSV65965867; called by muse, mutect2, varscan2
- CACNA1F | c.4662C>A p.I1554= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100544316; called by muse, mutect2, varscan2
- CHMP7 | c.777C>T p.S259= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as COSV100500630, COSV57533314; called by muse, mutect2, varscan2
- CPXM2 | c.1770C>T p.V590= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs369681113, COSV99582499; called by muse, mutect2, varscan2
- CUX2 | c.2613C>T p.Y871= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs778876224, COSV99919912; called by muse, mutect2
- EDEM2 | c.576G>A p.T192= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs78639611; called by muse, mutect2, varscan2
- FAM71C | c.216C>G p.G72= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100175757; called by muse, mutect2, varscan2
- FBLIM1 | c.66C>T p.R22= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs1229372791, COSV100181774; called by muse, mutect2, varscan2
- GPR50 | c.903C>T p.F301= | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as COSV99506251; called by muse, mutect2, varscan2
- HOXA5 | c.135C>T p.Y45= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56075540; called by muse, mutect2, varscan2
- ING1 | c.1017A>C p.R339= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100312196; called by muse, mutect2, varscan2
- KCTD17 | c.519C>T p.I173= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs34395802; called by muse, mutect2, varscan2
- LCE1C | c.144C>T p.S48= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as rs747442143, COSV100908448; called by muse, mutect2, varscan2
- MIEF1 | c.1149C>T p.S383= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100307723; called by muse, mutect2, varscan2
- MRTFA | c.348C>T p.S116= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100844123, COSV62934442; called by muse, mutect2
- NECAB2 | c.657C>T p.P219= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs34348308, COSV100534120, COSV59421180; called by muse, mutect2, varscan2
- NLGN4X | c.1143C>T p.D381= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs764507720, COSV52042984, COSV99319681; called by muse, mutect2, varscan2
- NLRC4 | c.3054T>G p.A1018= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV99249757; called by muse, mutect2, varscan2
- NOP9 | c.1314G>A p.R438= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV51868481; called by muse, mutect2
- NOS1 | c.117G>T p.P39= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100500354; called by muse, mutect2, varscan2
- PAX3 | c.282C>A p.G94= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99286633; called by muse, mutect2
- PCDH17 | c.564C>T p.D188= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV64974959, COSV64975590; called by muse, mutect2, varscan2
- PCDHB16 | c.1608C>T p.R536= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs1295307551; called by muse, mutect2, varscan2
- PRKDC | c.8961A>G p.T2987= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100041063; called by muse, mutect2, varscan2
- RLBP1 | c.762C>T p.V254= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs762020753, COSV99175342; called by muse, varscan2
- RNF165 | c.180G>A p.S60= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99491767; called by muse, mutect2, varscan2
- SALL3 | c.2631C>T p.N877= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs367651872; called by muse, mutect2, varscan2
- SARAF | c.975G>A p.T325= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs755489043, COSV99822788; called by muse, mutect2, varscan2
- STK32C | c.619C>T p.L207= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100062703; called by muse, mutect2, varscan2
- TACR2 | c.597C>A p.L199= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100964811, COSV64822066; called by muse, mutect2
- TBC1D1 | c.1845G>A p.P615= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs528041274, COSV99791463; called by muse, mutect2, varscan2
- TNFRSF18 | c.725G>A p.*242= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100148905; called by muse, mutect2, varscan2
- TNFSF11 | c.828C>T p.N276= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs199774248, CD073711, COSV99520548; called by muse, mutect2, varscan2
- TUBB8 | c.585C>T p.N195= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as rs550484517, COSV59114509; called by muse, mutect2, varscan2
- UBE3B | c.1311G>A p.S437= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs1260220803, COSV55094378; called by muse, mutect2, varscan2
- ZBTB12 | c.645G>A p.S215= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs370274844; called by muse, mutect2, varscan2
- ZIC1 | c.57G>A p.A19= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs756393471, COSV51550355, COSV51557226; called by muse, mutect2, varscan2
- ZIC1 | c.1041C>T p.S347= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV51554209, COSV51554742, COSV51558211; called by muse, varscan2
- ZNF536 | c.336C>A p.G112= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100835335; called by muse, mutect2, varscan2
- CES2 | chr16:66935496 A>T | 5'Flank (SNP) | VAF 61/121 reads (50%) | catalogued as COSV100399279; called by muse, mutect2, varscan2
- SNORD116-3 | n.74G>A | RNA (SNP) | VAF 62/150 reads (41%) | catalogued as rs568283973; called by muse, varscan2
- VPS11 | c.-972T>C | 5'UTR (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100333815; called by muse, mutect2, varscan2
